Somatic mutation profile of tumor specimen TCGA-78-7537-01A (aliquot TCGA-78-7537-01A-11D-2063-08) from TCGA case TCGA-78-7537, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 72.9 years (26,610 days).
Specimen TCGA-78-7537-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a2e1f32-0d07-45f5-8567-f6310bdfd9d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-78-7537-10A (Blood Derived Normal), aliquot TCGA-78-7537-10A-01D-2063-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32b0df94-fc9d-4a51-b207-37c844f4e931

The open-access MAF lists 147 somatic variants for this specimen: 121 protein-altering or splice-affecting, 23 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 96, Silent 23, Nonsense Mutation 9, Frame Shift Del 7, Splice Site 4, Frame Shift Ins 2, Intron 2, In Frame Del 1, Nonstop Mutation 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1517G>T p.G506V (on ENST00000288602 / NM_001374244.1; = p.G466V on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs121913351, CM115083, COSV56057462, COSV56059390, COSV56070593; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AACS | c.1753C>G p.L585V | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55535496; called by muse, mutect2, varscan2
- AARS2 | c.786del p.H263Mfs*47 | Frame Shift Del (DEL) | VAF 5/37 reads (14%) | catalogued as COSV55117486; called by mutect2, pindel, varscan2
- ABCB1 | c.122G>T p.R41L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55945290, COSV55947749; called by muse, mutect2, varscan2
- ADAMTS17 | c.2023G>A p.G675S | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1486295146, COSV51475458, COSV51476046; called by muse, mutect2, varscan2
- AHNAK2 | c.13444A>T p.I4482F | Missense Mutation (SNP) | VAF 113/314 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.883); catalogued as COSV60911325; called by muse, mutect2, varscan2
- AP3S2 | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 74/215 reads (34%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs1353945044, COSV60517788; called by muse, mutect2, varscan2
- APAF1 | c.2068G>A p.E690K (on ENST00000551964 / NM_181861.2; = p.E679K on NM_001160.3) | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV59662632; called by muse, mutect2, varscan2
- ARAP3 | c.1422G>T p.W474C | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53349652; called by muse, mutect2, varscan2
- ASB5 | c.286G>C p.V96L | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs575382169, COSV56669475; called by muse, mutect2, varscan2
- BMT2 | c.22C>G p.R8G | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.011); catalogued as COSV51775679; called by muse, mutect2, varscan2
- BRSK2 | c.737T>C p.L246P | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57541707; called by muse, mutect2, varscan2
- C2orf16 | c.2999C>T p.T1000I | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.056); catalogued as COSV62674529; called by muse, mutect2, varscan2
- CACNG7 | c.20G>T p.R7L | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.519); catalogued as COSV55813699, COSV55815603; called by muse, mutect2, varscan2
- CALB2 | c.337A>G p.M113V | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV56938628; called by muse, mutect2, varscan2
- CASC3 | c.785+1G>T p.X262_splice | Splice Site (SNP) | VAF 26/66 reads (39%) | catalogued as COSV52866821; called by muse, mutect2, varscan2
- CD4 | c.365T>C p.V122A | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV50589807; called by muse, mutect2, varscan2
- CLDN8 | c.252G>T p.M84I | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54525688; called by muse, mutect2, varscan2
- CLEC4C | c.189G>T p.Q63H | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.747); catalogued as COSV63582430; called by muse, mutect2, varscan2
- CNMD | c.533C>A p.P178H | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV65032691; called by muse, mutect2, varscan2
- COL11A1 | c.3176C>A p.P1059Q | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as COSV62172423, COSV62198672; called by muse, mutect2, varscan2
- CR1 | c.4630G>T p.V1544L | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV65457076; called by muse, mutect2, varscan2
- CRYGC | c.95G>T p.R32L | Missense Mutation (SNP) | VAF 63/184 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.606); catalogued as COSV56408799, COSV56410000; called by muse, mutect2, varscan2
- CRYZ | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1303968426, COSV61717345; called by muse, mutect2, varscan2
- CSMD3 | c.1241G>T p.G414V | Missense Mutation (SNP) | VAF 63/159 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV52135678, COSV99820384; called by muse, mutect2, varscan2
- CTSV | c.542G>T p.G181V | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52344513; called by muse, mutect2, varscan2
- DMRT1 | c.764A>T p.N255I | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV66520448; called by muse, mutect2, varscan2
- DSG2 | c.2476T>G p.L826V | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55197960; called by muse, mutect2
- EIF6 | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 237/328 reads (72%) | catalogued as COSV55769040; called by muse, mutect2, varscan2
- EMILIN2 | c.205C>A p.Q69K | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.515); catalogued as rs1160046345, COSV54422257; called by muse, mutect2, varscan2
- EPO | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 72/211 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.8); catalogued as COSV53161204; called by muse, mutect2, varscan2
- EXT1 | c.492C>G p.D164E | Missense Mutation (SNP) | VAF 76/206 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV65476904; called by muse, mutect2, varscan2
- FLCN | c.1226A>T p.Y409F | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as COSV53258136; called by muse, mutect2, varscan2
- FSHR | c.431T>A p.L144H | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV58620284; called by muse, mutect2, varscan2
- GABRG1 | c.253+1G>A p.X85_splice | Splice Site (SNP) | VAF 28/77 reads (36%) | catalogued as COSV54951551; called by muse, mutect2, varscan2
- GALC | c.1165C>T p.H389Y | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as COSV54324182; called by muse, mutect2, varscan2
- GIT2 | c.2210A>G p.Q737R (on ENST00000355312 / NM_057169.5; = p.Q659R on NM_014776.5) | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1172685612, COSV58079478; called by muse, mutect2, varscan2
- GLP2R | c.1122G>C p.M374I | Missense Mutation (SNP) | VAF 66/179 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV52323205; called by muse, mutect2, varscan2
- HAPLN1 | c.446C>T p.T149I | Missense Mutation (SNP) | VAF 57/174 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.716); catalogued as COSV57146606, COSV57148070; called by muse, mutect2, varscan2
- HCN3 | c.2273C>T p.P758L | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.227); catalogued as COSV61360768; called by muse, mutect2, varscan2
- HNRNPA1 | c.889G>T p.G297C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs372023836, COSV52936114; called by muse, mutect2, varscan2
- HTR4 | c.1148T>A p.L383Q | Missense Mutation (SNP) | VAF 60/209 reads (29%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.003); catalogued as COSV58792083; called by muse, mutect2, varscan2
- ITPR3 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 63/214 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65406795; called by muse, mutect2, varscan2
- KBTBD8 | c.1582G>T p.V528L | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV55127643; called by muse, mutect2, varscan2
- KCND3 | c.360C>G p.F120L | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56177690; called by muse, mutect2, varscan2
- KCNF1 | c.1367C>A p.P456H | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.07); catalogued as COSV54462521; called by muse, mutect2, varscan2
- KCNQ3 | c.519G>C p.L173F | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.906); catalogued as COSV66466813; called by muse, mutect2, varscan2
- KNDC1 | c.1522G>A p.D508N | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV58833826; called by muse, mutect2, varscan2
- KRT73 | c.80del p.G27Afs*91 | Frame Shift Del (DEL) | VAF 47/137 reads (34%) | catalogued as rs771858764; called by mutect2, pindel, varscan2
- L1CAM | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62827398; called by muse, mutect2, varscan2
- LDLR | c.2354G>T p.S785I | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.043); catalogued as COSV52942330; called by muse, mutect2, varscan2
- LILRA6 | c.1384G>T p.G462W | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54432374; called by muse, mutect2, varscan2
- LINGO3 | c.1720G>T p.G574W | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68261144; called by muse, mutect2, varscan2
- MAN2C1 | c.820A>T p.R274W | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51227181; called by muse, mutect2, varscan2
- MAST3 | c.2833G>T p.G945C | Missense Mutation (SNP) | VAF 61/150 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV53218892; called by muse, mutect2, varscan2
- MCM10 | c.766A>T p.R256W (on ENST00000484800 / NM_182751.3; = p.R255W on NM_018518.5) | Missense Mutation (SNP) | VAF 60/182 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV66333574; called by muse, mutect2, varscan2
- MMD | c.310A>T p.I104F | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50434402; called by muse, mutect2, varscan2
- MYOM1 | c.4134C>A p.C1378* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as COSV55288013; called by muse, mutect2, varscan2
- MYT1 | c.86+1G>T p.X29_splice | Splice Site (SNP) | VAF 47/621 reads (8%) | catalogued as COSV60502908; called by muse, mutect2
- NCOR1 | c.6656C>G p.S2219C | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as COSV51968080; called by muse, mutect2
- NT5E | c.649G>T p.A217S | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100004035; called by muse, mutect2, varscan2
- OR11H1 | c.658G>T p.G220* | Nonsense Mutation (SNP) | VAF 59/247 reads (24%) | catalogued as COSV53271757; called by muse, mutect2, varscan2
- OR14C36 | c.613G>T p.G205C | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.208); catalogued as COSV58600813; called by muse, mutect2, varscan2
- OR2L8 | c.755C>A p.A252E | Missense Mutation (SNP) | VAF 47/237 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV61726105, COSV61728344; called by muse, mutect2, varscan2
- OR51M1 | c.257G>T p.C86F | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as COSV60784146; called by muse, mutect2, varscan2
- OR5A1 | c.119C>A p.T40N | Missense Mutation (SNP) | VAF 56/157 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs1213077222, COSV57376084, COSV57376244; called by muse, mutect2, varscan2
- PCDHGA4 | c.1930G>T p.E644* | Nonsense Mutation (SNP) | VAF 38/108 reads (35%) | catalogued as COSV53919225, COSV99548615; called by muse, mutect2, varscan2
- PEG3 | c.2592T>A p.Y864* | Nonsense Mutation (SNP) | VAF 34/104 reads (33%) | catalogued as COSV55629177; called by muse, mutect2, varscan2
- PEX1 | c.404G>T p.R135L | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50395596, COSV50406081; called by muse, mutect2, varscan2
- PIWIL1 | c.2081C>A p.P694H | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55345238; called by muse, mutect2, varscan2
- PLK2 | c.1340T>A p.M447K | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as COSV57106416; called by muse, mutect2, varscan2
- PLPPR5 | c.700G>C p.A234P | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV54168593, COSV54170931; called by muse, mutect2, varscan2
- PNPLA6 | c.3123G>C p.K1041N (on ENST00000414982 / NM_001166111.2; = p.K993N on NM_006702.5) | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.774); catalogued as COSV55375672; called by muse, mutect2, varscan2
- PNPLA6 | c.3350C>T p.S1117L (on ENST00000414982 / NM_001166111.2; = p.S1069L on NM_006702.5) | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV55375693; called by muse, mutect2, varscan2
- POTED | c.1570C>A p.R524S | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV55047335; called by muse, mutect2, varscan2
- PTGS2 | c.1193C>T p.S398F | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as COSV66568577; called by muse, mutect2
- PTPRD | c.4300G>T p.E1434* | Nonsense Mutation (SNP) | VAF 51/171 reads (30%) | catalogued as COSV61932965, COSV61935427; called by muse, mutect2, varscan2
- REG4 | c.35T>A p.L12Q | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV56652433; called by muse, mutect2, varscan2
- RTL3 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 18/22 reads (82%) | catalogued as COSV58183583; called by muse, mutect2, varscan2
- SARAF | c.133C>G p.L45V | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV56357073; called by muse, mutect2, varscan2
- SCN5A | c.3553C>A p.Q1185K (on ENST00000333535 / NM_198056.3; = p.Q1184K on NM_000335.5) | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV61119663; called by muse, mutect2, varscan2
- SERINC1 | c.26C>T p.S9F | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV60101792; called by muse, mutect2, varscan2
- SEZ6 | c.1335G>T p.W445C | Missense Mutation (SNP) | VAF 48/187 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57978388; called by muse, mutect2, varscan2
- SFXN1 | c.490G>T p.G164* | Nonsense Mutation (SNP) | VAF 78/240 reads (33%) | catalogued as COSV58492900; called by muse, mutect2, varscan2
- SIRPB1 | c.75A>C p.T25= | Splice Region (SNP) | VAF 28/106 reads (26%) | catalogued as COSV54374732; called by muse, mutect2, varscan2
- SLC6A1 | c.344T>A p.V115E | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV55114159; called by muse, mutect2, varscan2
- SMOC1 | c.151C>T p.Q51* | Nonsense Mutation (SNP) | VAF 47/127 reads (37%) | catalogued as COSV62760131; called by muse, mutect2, varscan2
- SMPD4 | c.1471G>C p.A491P (on ENST00000409031 / NM_017951.4; = p.A462P on NM_017751.4) | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs138491461, COSV60079265; called by muse, mutect2, varscan2
- SPTAN1 | c.4582G>A p.E1528K | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.971); catalogued as rs780433514, COSV63986071; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.1226C>T p.S409F | Missense Mutation (SNP) | VAF 132/397 reads (33%) | PolyPhen probably damaging (0.983); catalogued as COSV50073512, COSV50073809; called by muse, mutect2, varscan2
- STYXL1 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as COSV50388165; called by muse, mutect2, varscan2
- TAS2R19 | c.37G>C p.V13L | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.457); catalogued as COSV66828147; called by muse, mutect2, varscan2
- TCFL5 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 43/332 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.759); catalogued as rs767486884, COSV53895877; called by muse, mutect2, varscan2
- TGFB1I1 | c.463A>G p.T155A (on ENST00000394863 / NM_001042454.3; = p.T138A on NM_015927.4) | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.038); catalogued as COSV62357510; called by muse, mutect2, varscan2
- THSD7B | c.2581G>T p.V861L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as COSV55668015; called by muse, mutect2, varscan2
- TMEM132E | c.1162G>T p.D388Y (on ENST00000321639; = p.D478Y on NM_001304438.2) | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV58695634; called by muse, mutect2, varscan2
- TTYH3 | c.199T>A p.W67R | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.936); catalogued as COSV51859332; called by muse, mutect2, varscan2
- USH2A | c.14171G>C p.S4724T | Missense Mutation (SNP) | VAF 57/190 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV56346923; called by muse, mutect2, varscan2
- USP6 | c.1841C>T p.P614L | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV51478507; called by muse, mutect2, varscan2
- VARS1 | c.635G>T p.G212V | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.255); catalogued as COSV65151686; called by muse, mutect2, varscan2
- VCAN | c.7345C>A p.Q2449K | Missense Mutation (SNP) | VAF 60/176 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.055); catalogued as COSV54101422; called by muse, mutect2, varscan2
- VEZF1 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1452010267, COSV51967821; called by muse, mutect2
- VN1R4 | c.232C>A p.L78I | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs1446864629, COSV60804596; called by muse, mutect2, varscan2
- VRTN | c.590A>T p.K197M | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV56439787; called by muse, mutect2, varscan2
- VWF | c.6378C>G p.I2126M | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.048); catalogued as COSV54615296; called by muse, mutect2, varscan2
- YTHDC2 | c.3951A>T p.E1317D | Missense Mutation (SNP) | VAF 72/215 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV50738620; called by muse, mutect2, varscan2
- ZBTB33 | c.137A>T p.H46L | Missense Mutation (SNP) | VAF 127/193 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58533474; called by muse, mutect2, varscan2
- ZMYND19 | c.683G>T p.*228Lext*79 | Nonstop Mutation (SNP) | VAF 16/63 reads (25%) | catalogued as COSV53021704, COSV53022359; called by muse, mutect2, varscan2
- ZNF195 | c.1374G>C p.R458S (on ENST00000399602 / NM_001130520.3; = p.R386S on NM_007152.5) | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.963); catalogued as COSV50002571; called by muse, mutect2, varscan2
- ZSCAN1 | c.919T>A p.F307I | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.849); catalogued as COSV56602875; called by muse, mutect2, varscan2
- ZSCAN18 | c.1071G>T p.Q357H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as COSV53731172; called by muse, mutect2, varscan2
- HAL | c.309-1_316del p.X103_splice | Splice Site (DEL) | VAF 35/134 reads (26%) | called by mutect2, pindel, varscan2
- HSP90AB1 | c.85A>G p.I29V | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.812); called by muse, varscan2
- LAMB3 | c.3348dup p.G1117Wfs*43 | Frame Shift Ins (INS) | VAF 69/351 reads (20%) | called by mutect2, pindel, varscan2
- MED16 | c.368del p.G123Afs*3 | Frame Shift Del (DEL) | VAF 14/32 reads (44%) | called by mutect2, pindel, varscan2
- NMUR2 | c.178del p.V60Sfs*10 | Frame Shift Del (DEL) | VAF 25/79 reads (32%) | called by mutect2, pindel, varscan2
- RBM10 | c.489del p.N164Tfs*102 | Frame Shift Del (DEL) | VAF 16/28 reads (57%) | called by mutect2, pindel, varscan2
- SATB1 | c.980_991del p.L327_Y331delinsH | In Frame Del (DEL) | VAF 29/115 reads (25%) | called by mutect2, pindel, varscan2
- STK11 | c.526del p.D176Tfs*111 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- USP29 | c.694_695insC p.C232Sfs*2 | Frame Shift Ins (INS) | VAF 42/124 reads (34%) | called by mutect2, pindel*, varscan2
- ZNF28 | c.1586del p.G529Afs*95 | Frame Shift Del (DEL) | VAF 41/156 reads (26%) | called by mutect2, pindel, varscan2
- AGRN | c.1587G>T p.A529= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV101038732, COSV65071872; called by muse, mutect2, varscan2
- AK5 | c.255T>A p.P85= (on ENST00000354567 / NM_174858.3; = p.P59= on NM_012093.4) | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV58355176; called by muse, mutect2, varscan2
- AKAP13 | c.6045C>T p.I2015= (on ENST00000394518 / NM_007200.5; = p.I2019= on NM_006738.6) | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as rs866188598, COSV63452353; called by muse, mutect2, varscan2
- ATF6B | c.492G>A p.K164= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV64351522; called by muse, mutect2, varscan2
- DES | c.780G>A p.Q260= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as COSV100900463, COSV64660064; called by muse, mutect2, varscan2
- DNAAF5 | c.1719G>T p.S573= | Silent (SNP) | VAF 35/146 reads (24%) | catalogued as COSV52415406; called by muse, mutect2, varscan2
- EVC | c.2280G>T p.R760= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV53830707; called by muse, mutect2, varscan2
- GLI3 | c.3393G>T p.A1131= | Silent (SNP) | VAF 60/176 reads (34%) | catalogued as rs1171117438, COSV67886652, COSV67889536; called by muse, mutect2, varscan2
- HELLS | c.1104G>A p.R368= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV53295538; called by muse, mutect2, varscan2
- HROB | c.1380G>T p.T460= | Silent (SNP) | VAF 44/102 reads (43%) | catalogued as COSV55369155; called by muse, mutect2, varscan2
- LYST | c.5706A>G p.V1902= | Silent (SNP) | VAF 36/120 reads (30%) | catalogued as COSV67705243; called by muse, mutect2, varscan2
- MNS1 | c.1134T>A p.T378= | Silent (SNP) | VAF 51/147 reads (35%) | catalogued as COSV53067885; called by muse, mutect2, varscan2
- NECAP2 | c.576A>T p.P192= | Silent (SNP) | VAF 31/104 reads (30%) | catalogued as COSV61433160; called by muse, mutect2, varscan2
- NFATC2IP | c.1050C>A p.L350= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV57909944; called by muse, mutect2, varscan2
- NLRP5 | c.1434C>T p.C478= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs537345559, COSV66762764; called by muse, mutect2, varscan2
- PDCD6IP | c.762C>T p.A254= | Silent (SNP) | VAF 36/116 reads (31%) | catalogued as COSV56242057; called by muse, mutect2, varscan2
- PHF3 | c.5307C>T p.N1769= | Silent (SNP) | VAF 35/105 reads (33%) | catalogued as rs1157719610, COSV50315257; called by muse, mutect2, varscan2
- PHF8 | c.816C>T p.L272= (on ENST00000357988 / NM_001184896.1; = p.L236= on NM_015107.3) | Silent (SNP) | VAF 34/49 reads (69%) | catalogued as COSV57679047; called by muse, mutect2, varscan2
- PNPLA1 | c.801C>T p.S267= (on ENST00000394571 / NM_001374623.1; = p.S172= on NM_173676.2) | Silent (SNP) | VAF 25/86 reads (29%) | catalogued as COSV57233424; called by muse, mutect2, varscan2
- TRBV5-1 | c.279T>A p.S93= | Silent (SNP) | VAF 31/78 reads (40%) | called by muse, mutect2, varscan2
- VGLL3 | c.750T>A p.P250= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV67352663; called by muse, mutect2, varscan2
- XDH | c.381G>T p.L127= | Silent (SNP) | VAF 54/149 reads (36%) | catalogued as COSV65147719; called by muse, mutect2, varscan2
- Z83844.2 | c.1353G>T p.P451= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as COSV60927716; called by muse, mutect2
- CACNA2D1 | c.1931-700G>C | Intron (SNP) | VAF 6/28 reads (21%) | catalogued as COSV62375619, COSV62384894, COSV62393722; called by muse, mutect2, varscan2
- MGAM | c.4618+5574C>T | Intron (SNP) | VAF 22/68 reads (32%) | catalogued as rs1296245800, COSV101527442; called by muse, mutect2, varscan2
- ZNF22 | chr10:45000717 del G | 5'Flank (DEL) | VAF 13/44 reads (30%) | called by mutect2, pindel, varscan2
